Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6406, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6406-01A (Primary Tumor).

[page 1 of 2]
SURGERY DATE: [REDACTED]

RECEIVE DATE: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, LEFT FRONTAL, EXCISION: HIGH HISTOLOGICAL GRADE
GLIOMA, MIXED OLIGOASTROCYTIC /MIB-1 LABELLING INDEX 22%.

SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: Brain, left frontal.

Clinical History and Pre-Op Dx: [REDACTED] with large frontal
brain tumor.

GROSS PATHOLOGY:

- A. Received fresh, several fragments, 1.8 cm across in aggregate.
Semi-firm, grayish-white, glistening. In total #1-4.

INTRAOPERATIVE CONSULTATION: Brain, left frontal: Malignant
neoplasm,
consistent with glioma.

- B. Received fresh, several fragments, 3.5 cm across in aggregate.
Semi-firm, grayish-white, glistening. In total #5-8.

MICROSCOPIC: A,B. Portions of a glial neoplastic proliferation. The
neoplastic cells are medium-sized, have hyperchromatic pleomorphic
nuclei, and the nuclear outline tends to be elongated or ovoid. In
the

background there is a uniform finely fibrillary internuclear space.
Throughout the neoplasm there are branching small vessels, frequently
arciform. There are frequent mitotic figures, and there are focal
areas of tumor necrosis and prominent microvascular cellular
proliferation. Rather rarely, there are clear halos around neoplastic
nuclei. In a couple of areas there is chunky microcalcification.

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were
performed on sections from block #2.

The GFAP highlights the fine gliofibrillary background. With the MIB-
1, a proliferation index of 22% is determined in the more active
areas.

COMMENT: The neoplasm is a solid cellular glial neoplastic
proliferation with features of anaplasia, including prominent nuclear
pleomorphism and atypia, prominent mitotic activity, and focal tumor
necrosis with focal microvascular cellular proliferation. The
proliferation index is high at about 22% The predominant cellular

[page 2 of 2]
pattern and architecture are interpreted as oligodendroglial in nature, however with some astrocytic component. This neoplasm could also be classified as anaplastic oligodendroglioma.

Source: NCI Genomic Data Commons file c8c680ac-eec1-47ea-9492-62489dd5bba9 (TCGA-DU-6406.84775A3E-6DEB-477C-BD7B-65F84D5701DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).